CCDI case PBCDEY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/8bb7c905-cf75-4c7c-bb9b-3809ab95f261

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 18.0 years (6,562 days).

Biospecimens (3 samples)
- Sample 0DPE93: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPE9C, 0DPE9K (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
